CPTAC case C3N-03765 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4762e4eb-bed9-43b9-a5d9-ebe93c0f7541

Demographics
Sex at birth: male; Race: white; Year of birth: 1957; Vital status: Dead; Days to death: 827 days (2.3 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 60.9 years (22,260 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 827 days (2.3 years); Progression or recurrence: yes; Days to last follow up: 719 days (2.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm; Lymph node involvement: Positive; Lymph nodes positive: 1; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 348 days; Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 348 days; Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 348 days; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 719 days (2.0 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 2.

Other clinical attributes
- Weight: 93 kg; Height: 175 cm; BMI: 30.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03765-07: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 262 mg; Time between excision and freezing: 4 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03765-27: Section location: Right Upper Lobe; Percent tumor nuclei: 75; Percent necrosis: 5.
- Sample C3N-03765-09: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -9 days; Initial weight: 185 mg; Time between excision and freezing: 4 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03765-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -9 days; Method of sample procurement: Blood Draw.
